Somatic mutation profile of tumor specimen TCGA-24-2267-01A (aliquot TCGA-24-2267-01A-01W-0799-08) from TCGA case TCGA-24-2267, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 58.3 years (21,293 days).
Specimen TCGA-24-2267-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff3f15c-ffb2-41a5-95cf-f8916c1926e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2267-11A (Solid Tissue Normal), aliquot TCGA-24-2267-11A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0639f02-264e-4e7e-b89f-074e050d6dbf

The open-access MAF lists 137 somatic variants for this specimen: 108 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 93, Silent 29, Frame Shift Del 5, Splice Site 4, In Frame Del 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS1 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60221087; called by muse, varscan2
- ACTL8 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 32/141 reads (23%) | catalogued as COSV64861614; called by muse, mutect2, varscan2
- ADGRG4 | c.8612T>G p.V2871G | Missense Mutation (SNP) | VAF 99/433 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54958112; called by muse, mutect2, varscan2
- AGO2 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV99595648; called by muse, mutect2
- ALK | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); catalogued as COSV66571366; called by muse, mutect2, varscan2
- APOB | c.9262C>A p.Q3088K | Missense Mutation (SNP) | VAF 288/517 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51925387, COSV51938555; called by muse, mutect2, varscan2
- ARL11 | c.46G>T p.V16L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.545); catalogued as COSV56291387; called by muse, mutect2, varscan2
- ARL4D | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV60721562; called by muse, mutect2, varscan2
- ATP10A | c.3631G>T p.A1211S | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.239); catalogued as COSV63517153, COSV63518435; called by muse, mutect2, varscan2
- BPNT2 | c.806C>G p.A269G | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52906675, COSV52907754; called by muse, mutect2, varscan2
- CC2D2B | c.882A>C p.E294D | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV60358114; called by muse, mutect2, varscan2
- CHST2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.881); catalogued as COSV58885848; called by muse, mutect2, varscan2
- CIB4 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV56601290; called by muse, mutect2, varscan2
- CLEC11A | c.842A>C p.H281P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV51574202; called by muse, mutect2, varscan2
- CNTRL | c.1445A>C p.Q482P | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as rs1190163316, COSV53048100; called by muse, mutect2, varscan2
- COBLL1 | c.3344C>G p.S1115C (on ENST00000392717; = p.S1077C on NM_014900.5) | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV52069334; called by muse, mutect2, varscan2
- COL15A1 | c.3654G>T p.L1218= | Splice Region (SNP) | VAF 78/271 reads (29%) | catalogued as rs1037857103, COSV66645884; called by muse, mutect2, varscan2
- COP1 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100443177; called by muse, mutect2
- CUL2 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs1195805295, COSV66079431; called by muse, mutect2, varscan2
- DCHS1 | c.1612T>A p.Y538N | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV55031624, COSV55036627; called by muse, mutect2, varscan2
- DMD | c.10690C>A p.L3564I | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58913951, COSV58916716; called by muse, mutect2, varscan2
- DNAH9 | c.5099C>A p.T1700N | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as COSV52353636; called by muse, mutect2, varscan2
- DNTT | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373710274, COSV64523101; called by muse, mutect2, varscan2
- DSC1 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57144438; called by muse, mutect2, varscan2
- FAM13C | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 219/1269 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs773688669, COSV53248736, COSV53249836; called by muse, mutect2, varscan2
- GARS1 | c.1125G>T p.L375F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); catalogued as COSV66828530; called by muse, mutect2, varscan2
- GFRA1 | c.500G>C p.C167S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100815687; called by muse, mutect2, varscan2
- GK2 | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 87/428 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1171405467, COSV62627274; called by muse, mutect2, varscan2
- GSTA2 | c.103A>T p.I35L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV72415020; called by muse, mutect2, varscan2
- GUCY2C | c.67A>G p.S23G | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV53791078; called by muse, mutect2, varscan2
- HMCES | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67300515; called by muse, mutect2, varscan2
- HMCN1 | c.1473G>T p.L491F | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1305962921, COSV99628393; called by muse, mutect2, varscan2
- HNRNPA3 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1464275340, COSV66820861; called by muse, mutect2, varscan2
- IFIH1 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs35207787, COSV55127334; called by muse, mutect2, varscan2
- IGSF21 | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs748938162, COSV52127521; called by muse, mutect2, varscan2
- INSR | c.525C>A p.N175K | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57164213; called by muse, mutect2, varscan2
- KCNE3 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs17221833, COSV59552002, COSV59552113; called by muse, mutect2, varscan2
- KCNMB1 | c.276C>A p.H92Q | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99210853; called by muse, mutect2
- KIAA1614 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV62552943; called by muse, mutect2
- LAMA1 | c.9142A>G p.S3048G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101056178; called by muse, mutect2
- LHX8 | c.911C>A p.P304Q | Missense Mutation (SNP) | VAF 79/530 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53957242; called by muse, mutect2, varscan2
- LRRC23 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV50389930; called by muse, mutect2, varscan2
- MAGEA11 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 20/634 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290488; called by muse, mutect2
- MAP1A | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750179744, COSV55809625; called by muse, mutect2, varscan2
- MEFV | c.2216A>C p.H739P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV54819905, COSV54821132; called by muse, mutect2, varscan2
- MINDY2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.057); catalogued as COSV57507081; called by muse, mutect2, varscan2
- MITF | c.1268A>C p.N423T (on ENST00000448226 / NM_006722.3; = p.N323T on NM_000248.4) | Missense Mutation (SNP) | VAF 97/444 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV58832229; called by muse, mutect2, varscan2
- MYO16 | c.2932A>G p.T978A | Missense Mutation (SNP) | VAF 42/256 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV51798571; called by muse, mutect2, varscan2
- MYOCD | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV58504984; called by muse, mutect2, varscan2
- NBAS | c.6448A>T p.I2150F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV55724502; called by muse, mutect2, varscan2
- NCAPD2 | c.2785C>A p.L929M | Missense Mutation (SNP) | VAF 27/447 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100217111; called by muse, mutect2
- NDUFB2 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 161/465 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV52595620; called by muse, mutect2, varscan2
- NFYB | c.592-1G>T p.X198_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as rs746662422, COSV99527165; called by mutect2, varscan2
- NKAP | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65056337; called by muse, mutect2, varscan2
- NRXN2 | c.3241G>A p.D1081N | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs749967463, COSV55454915; called by muse, mutect2, varscan2
- NTAN1 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99816892; called by muse, mutect2, varscan2
- OR2F2 | c.94T>A p.L32M | Missense Mutation (SNP) | VAF 382/1379 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV101283826, COSV101283839, COSV68832894; called by muse, mutect2, varscan2
- OR5B2 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 222/910 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV56907734, COSV56908475; called by muse, mutect2, varscan2
- OTOGL | c.2879A>G p.D960G (on ENST00000547103; = p.D951G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101509214; called by muse, mutect2
- PAPLN | c.2983A>G p.I995V (on ENST00000554301; = p.I968V on NM_173462.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs757852624, COSV53719049; called by muse, mutect2, varscan2
- PAXIP1 | c.1125T>G p.N375K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.621); catalogued as COSV68186347; called by muse, mutect2
- PCDHB2 | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs201070541, COSV50579315, COSV99165043; called by muse, mutect2, varscan2
- PCDHB7 | c.902T>C p.L301P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV50775154; called by muse, mutect2, varscan2
- PCK2 | c.748G>C p.G250R | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201974284; called by muse, mutect2, varscan2
- PIR | c.136A>G p.K46E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV62917093; called by muse, mutect2, varscan2
- POP7 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100292173; called by muse, mutect2, varscan2
- PPP1R9A | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56896061; called by muse, mutect2, varscan2
- PUS10 | c.210A>C p.K70N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV57452862; called by muse, mutect2, varscan2
- RYR2 | c.3658del p.D1220Mfs*5 | Frame Shift Del (DEL) | VAF 86/291 reads (30%) | catalogued as COSV63686880; called by mutect2, pindel, varscan2
- SCTR | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50028638; called by muse, mutect2, varscan2
- SERPINA9 | c.1188G>T p.M396I | Missense Mutation (SNP) | VAF 103/633 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs769630965, COSV54075730; called by muse, mutect2, varscan2
- SLC2A4 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV50301187; called by muse, mutect2, varscan2
- SNAI2 | c.400A>G p.N134D | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV50079289; called by muse, mutect2, varscan2
- SOX5 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 50/453 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV58632718; called by muse, mutect2
- STAG2 | c.2162A>T p.E721V | Missense Mutation (SNP) | VAF 75/615 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV54360609; called by muse, mutect2, varscan2
- STXBP4 | c.6T>G p.N2K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV54842039; called by muse, mutect2, varscan2
- TANC2 | c.1201C>G p.P401A | Missense Mutation (SNP) | VAF 180/1034 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV101267296, COSV101267388; called by muse, mutect2, varscan2
- TBC1D10A | c.302A>G p.H101R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV53164564; called by muse, mutect2, varscan2
- TBL3 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV60341823; called by muse, mutect2, varscan2
- TEC | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761626081, COSV51919098; called by muse, mutect2
- TENM1 | c.2011A>T p.T671S | Missense Mutation (SNP) | VAF 249/1214 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV64433763; called by muse, mutect2, varscan2
- TEX43 | c.307C>G p.P103A | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV64036182; called by muse, mutect2, varscan2
- TGIF1 | c.79G>T p.V27L (on ENST00000330513 / NM_001374396.1; = p.V47L on NM_003244.4) | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57908011; called by muse, mutect2, varscan2
- TMEM68 | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV58171320; called by muse, mutect2, varscan2
- TNFAIP8 | c.299A>C p.E100A | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV57227474; called by muse, mutect2, varscan2
- TP53 | c.850del p.T284Qfs*61 | Frame Shift Del (DEL) | VAF 55/117 reads (47%) | catalogued as CM156903, COSV52809281, COSV52896079, COSV53120916, COSV53272353; called by mutect2, pindel, varscan2
- TRMT1L | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1441063287, COSV62272493; called by muse, mutect2, varscan2
- TSPAN10 | c.874G>T p.V292F (on ENST00000574882 / NM_001290212.1; = p.V254F on NM_031945.4) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as COSV58507553; called by muse, mutect2, varscan2
- TUBD1 | c.1268T>C p.I423T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV57873147; called by muse, mutect2, varscan2
- UBQLN3 | c.1316C>T p.T439I | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61164469; called by muse, mutect2, varscan2
- UGT1A3 | c.842G>C p.C281S | Missense Mutation (SNP) | VAF 88/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201755757, COSV59390405; called by muse, mutect2, varscan2
- VPS13D | c.12663-2A>G p.X4221_splice | Splice Site (SNP) | VAF 26/77 reads (34%) | catalogued as COSV50644951; called by muse, mutect2, varscan2
- VPS8 | c.1501A>G p.R501G (on ENST00000625842 / NM_001349294.1; = p.R499G on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/391 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV54987757; called by muse, mutect2, varscan2
- XAGE5 | c.218C>A p.S73* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV63567945; called by muse, mutect2, varscan2
- XYLT1 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 16/514 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.088); catalogued as rs1281209696, COSV99761475; called by muse, mutect2
- ZNF182 | c.743A>G p.H248R | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.665); catalogued as COSV100527012; called by muse, mutect2
- ZNF318 | c.4831G>A p.D1611N | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV58933299; called by muse, mutect2, varscan2
- ZNF425 | c.1402A>C p.K468Q | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV65201538; called by muse, mutect2
- ZNF655 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV53158935; called by muse, mutect2, varscan2
- ZNF676 | c.1589T>C p.I530T (on ENST00000650058; = p.I498T on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV101236182; called by muse, mutect2
- CREBBP | c.3755_3777del p.G1252Dfs*9 | Frame Shift Del (DEL) | VAF 21/138 reads (15%) | called by mutect2, pindel
- DHTKD1 | c.210_242del p.A71_A81del | In Frame Del (DEL) | VAF 53/481 reads (11%) | called by mutect2, pindel
- HINFP | c.1056_1076del p.K352_N358del | In Frame Del (DEL) | VAF 52/328 reads (16%) | called by mutect2, pindel
- ITPRID2 | c.1766_1770del p.R589Ifs*3 | Frame Shift Del (DEL) | VAF 31/188 reads (16%) | called by mutect2, pindel, varscan2
- PLCH1 | c.1770_1789del p.R591Lfs*6 (on ENST00000340059 / NM_001130960.2; = p.R603Lfs*6 on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/332 reads (10%) | called by mutect2, pindel
- RAB3IP | c.1043_1065+2del p.X348_splice (on ENST00000550536 / NM_175623.4; = p.X332_splice on NM_022456.5) | Splice Site (DEL) | VAF 4/51 reads (8%) | called by mutect2, pindel
- RNF213 | c.6184-1_6195del p.X2062_splice | Splice Site (DEL) | VAF 8/102 reads (8%) | called by mutect2, pindel
- SLC19A3 | c.718_753del p.T240_S251del | In Frame Del (DEL) | VAF 29/137 reads (21%) | called by mutect2, pindel
- ABCC11 | c.2505G>A p.S835= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1200457896, COSV62323667; called by muse, mutect2, varscan2
- ADAMTSL1 | c.147C>T p.C49= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as rs895343655, COSV52807809; called by muse, mutect2, varscan2
- ASPHD2 | c.144C>T p.T48= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs150944010; called by muse, mutect2, varscan2
- FOCAD | c.378T>C p.S126= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as COSV58100816; called by muse, mutect2, varscan2
- GSTP1 | c.483G>T p.L161= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV66992532; called by muse, mutect2, varscan2
- HSD3B2 | c.825T>C p.F275= | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as COSV65593380; called by muse, mutect2, varscan2
- IFNA4 | c.355C>T p.L119= | Silent (SNP) | VAF 177/411 reads (43%) | catalogued as COSV70180028; called by muse, mutect2, varscan2
- IGLV7-46 | c.123T>C p.C41= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- IVL | c.528G>A p.P176= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs11205136, COSV64215846; called by muse, varscan2
- KIRREL3 | c.1521C>T p.S507= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as rs753433027, COSV101375240, COSV69384049; called by muse, mutect2, varscan2
- KPTN | c.570C>T p.L190= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV57645296; called by muse, mutect2, varscan2
- LINGO4 | c.1275A>G p.A425= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV63214894; called by muse, mutect2, varscan2
- MPDZ | c.2331G>T p.G777= | Silent (SNP) | VAF 673/1607 reads (42%) | catalogued as COSV59943927; called by muse, mutect2, varscan2
- MYH11 | c.708C>T p.N236= | Silent (SNP) | VAF 43/321 reads (13%) | catalogued as rs768328532, COSV55548185; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- MYOF | c.2781C>T p.H927= | Silent (SNP) | VAF 118/320 reads (37%) | catalogued as COSV63705295; called by muse, mutect2, varscan2
- NRXN3 | c.912C>T p.D304= | Silent (SNP) | VAF 12/296 reads (4%) | catalogued as COSV100203298; called by muse, mutect2
- OR6C1 | c.438T>G p.S146= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV65573618; called by muse, mutect2
- PISD | c.1173T>C p.N391= (on ENST00000439502 / NM_001326412.1; = p.N357= on NM_014338.3) | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs375120020; called by muse, mutect2, varscan2
- PLCE1 | c.771C>T p.D257= | Silent (SNP) | VAF 55/238 reads (23%) | catalogued as COSV53353885; called by muse, mutect2, varscan2
- RAB3D | c.468C>T p.D156= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV55791731; called by muse, mutect2, varscan2
- RBPJ | c.126G>A p.E42= | Silent (SNP) | VAF 8/197 reads (4%) | catalogued as rs1220798387, COSV100623616; called by muse, mutect2
- RINT1 | c.579T>G p.S193= | Silent (SNP) | VAF 52/134 reads (39%) | catalogued as COSV57558909; called by muse, mutect2, varscan2
- RNF20 | c.645G>A p.E215= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs754351898, COSV66355711; called by muse, varscan2
- SIGLEC14 | c.1029C>T p.C343= | Silent (SNP) | VAF 12/184 reads (7%) | catalogued as COSV99707450; called by muse, mutect2
- SLC35E1 | c.738C>T p.F246= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV101290772, COSV68735970; called by muse, mutect2, varscan2
- TCF20 | c.1566C>G p.G522= | Silent (SNP) | VAF 204/852 reads (24%) | catalogued as COSV59492161; called by muse, varscan2
- TRPV3 | c.1632C>T p.Y544= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV56792100; called by muse, mutect2, varscan2
- ZMYM6 | c.669A>G p.K223= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV58184558, COSV58184632; called by muse, mutect2, varscan2
- ZNF142 | c.2280G>C p.L760= (on ENST00000411696 / NM_001379660.1; = p.L560= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV68744045; called by muse, mutect2, varscan2
